Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AE8R, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AE8R-TTP1-A (Primary Tumor).

[page 1 of 22]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED] +2056
NAME: [REDACTED]
BIRTHDATE: [REDACTED]

PATIENT NBR:
PAT TYPE: 0

PAGE #: 1
SEX: F
ADM DATE: [REDACTED] +803

ACCESSION:

OPER DATE: [REDACTED] +0

REQ DOC:

PROCEDURE: APMI

VERIFIED BY: [REDACTED]

ADDENDUM REPORT IMMUNOSTAINS: [REDACTED] +8

=====

Immunostains are performed here at the [REDACTED]. The malignant cells are positive for PAX-8 and pancytokeratin. This immunoprofile is consistent with primary renal cell carcinoma.

Please see diagnosis below.

PROCEDURE: APDX

VERIFIED BY:

Metastatic renal cell carcinoma. See COMMENT.

This case was seen in consultation with [REDACTED].

COMMENT:

Subtyping of this tumor is limited on this small biopsy, however, clear cell renal cell carcinoma is favored.

I, [REDACTED] signing staff pathologist, have personally examined and interpreted the slides from this case.

Code: [REDACTED]

[REDACTED]

"This test was developed and its performance characteristics determined by the [REDACTED] Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. (The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ["CLIA"] as qualified to perform high complexity testing)."

[REDACTED]

[page 2 of 22]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED] +2056
NAME
BIRTHDATE:

PATIENT NBR:
PAT TYPE: O

PAGE #: 2
SEX: F
ADM DATE: [REDACTED] +803

ACCESSION:

OPER DATE: [REDACTED] +0

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

No history provided.

PROCEDURE: SPGD

VERIFIED BY:

PROCEDURE: SPDX

-10 1. Left chest wall mass, fine needle aspiration and core bio.
[REDACTED]: Atypical cells suspicious for carcinoma. Please see COMMENT.

COMMENT:

Immunohistochemical stains and special stain with Alcian blue/PAS are performed at the outside institution and reviewed here. The neoplastic cells are positive for EMA and vimentin but are negative for cytokeratin 7, calretinin, cytokeratin cocktail, CEA, TTF1 and cytoplasmic mucin.

Immunohistochemical stains are performed at the outside institution but not reviewed here. The neoplastic cells are negative for muscle-specific actin, Alpha fetal protein, CD15, CD34, CD45, CD68, CD117, CK5/6, CK20, CK88, estrogen receptor, HER-2/neu, placental alkaline phosphatase, progesterone receptor, S100 protein and synaptophysin.

A tissue block has been requested; immunostain for PAX-8 will be performed if additional material is available.

Case seen in consultation with

I, [REDACTED] signing staff pathologist, have personally examined and interpreted the slides from this case.

[REDACTED]

[page 3 of 22]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED] +2056
NAME:
BIRTHDATE:

PATIENT NBR:
PAT TYPE: 0

PAGE #: 3
SEX: F
ADM DATE: [REDACTED] +803

ACCESSION:

OPER DATE: [REDACTED] +0

REQ DOC:

PROCEDURE:

VERIFIED BY:

ACCESSION:

OPER DATE: [REDACTED] +277

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

+0 Metastatic renal cell carcinoma s/p left nephrectomy and left chest wall mass.
angioembolization of [REDACTED] Surveillance CT increasing in size of right LL lung
nodule. Operative Procedure/Tissue Submitted: R vats wedge.

PROCEDURE: SPGD

VERIFIED BY:

1. "Diaphragm nodule [REDACTED] #1". A 0.3 cm red bit.
Frozen section control. [REDACTED]
2. "RLL wedge". A 6.5 x 1.9 x 1.0 cm wedge of lung with a 1.2 x 0.9 x 1.1 cm
tan-white nodule. It is located 0.5 cm away from the staple line. The staple
line is shaved with the underlying tissue inked blue. The pleura is pink-tan
with anthracotic pigmentation. Remaining lung parenchyma is unremarkable.
2A. Representative section of nodule to staple line.
Frozen section control. [REDACTED]
2B and C. Nodule to pleura and staple line. [REDACTED]
2D. Normal lung. [REDACTED]
3. "R diaphragm nodule". Received in formalin in a small container is a 2.1 x
1.7 x 0.5 cm irregular portion of red-brown fibromuscular tissue. One aspect
is partially covered by a membranous red tissue. Specimen is inked blue and
sectioned. The cut surface is red with focal area of fibrotic tissue. A
definite lesion is not identified.
3A and B. [REDACTED]
[REDACTED]

[page 4 of 22]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED] +2056
NAME:
BIRTHDATE: [REDACTED]

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

PAGE #: 4
SEX: F
ADM DATE: [REDACTED] +803

ACCESSION:

OPER DATE: [REDACTED] +277

REQ DOC:

FROZEN SECTION REPORT

1. Metastatic renal cell carcinoma
2. Metastatic clear cell renal cell carcinoma.

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPDX

VERIFIED BY:

1 and 3. Right diaphragm nodule, excision: Microscopic focus of metastatic renal cell carcinoma. Margins negative.

2. Lung, right lower lobe, wedge resection: Metastatic renal cell carcinoma, classic clear cell type (1.2 cm). Margins negative.

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:r

Code: [REDACTED]

ACCESSION:

OPER DATE: [REDACTED] +26

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Left renal mass. Clinical Diagnosis: Left renal mass concerning for renal cell carcinoma. Operative Procedure/Tissue Submitted: Ex-lap hand assisted cyto reductive nephrectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Left kidney." Received in formalin in a large container is a 400 gm, 12 x 8 x 7 cm kidney with a 6.5 x 5.5 x 5.2 cm, lobular yellow and tan mass with several small, up to 1.0 cm cysts containing blood and serous fluid, centered

[page 5 of 22]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED] +1873
NAME:
BIRTHDATE: - - -

PATIENT NBR:
PAT TYPE: O

PAGE #: 5
SEX: F
ADM DATE:

ACCESSION

OPER DATE: [REDACTED] +26

REQ DOC: - - -

on the cortex of the upper pole and extending into the medulla without involvement of the pelvis, abutting and focally penetrating the renal capsule, within 0.1 cm of the soft tissue margin (inked blue). The remaining renal parenchyma is unremarkable. No lymph nodes are identified. The adrenal gland is not present.

1A. Margins of renal vein, renal artery and ureter.

1B-C. Mass penetrating renal capsule. [REDACTED]

1D-F. Mass with closest soft tissue margin. [REDACTED]

1G. Mass to uninvolved parenchyma. [REDACTED]

1H. Mass to renal hilum. [REDACTED]

PROCEDURE: SPMI

VERIFIED BY:

RENAL NEOPLASM

PROCEDURE: Left laparoscopic nephrectomy.

TUMOR TYPE: Renal cell carcinoma, classic clear cell type.

SARCOMATOID DIFFERENTIATION: Absent.

FUHRMAN NUCLEAR GRADE: 4/4.

GROSS APPEARANCE: Solid and cystic.

SIZE: 6.8 cm.

EXTENT OF TUMOR: Tumor invades perirenal fat (T3a).

MARGIN STATUS:

VASCULAR: Negative.

URETERAL: Negative.

PARENCHYMAL: N/A.

SOFT TISSUE: Negative.

ANGIOLYMPHATIC INVASION (MICROSCOPIC): Present.

LYMPH NODES: Not assessed.

ADRENAL GLAND INVOLVEMENT: Not assessed.

[page 6 of 22]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED] +2056
NAME:
BIRTHDATE:

PATIENT NBR: -
PAT TYPE: 0

PAGE #: 6
SEX: F
ADM DATE: [REDACTED] +803

ACCESSION:

OPER DATE: [REDACTED] +26

REQ DOC: "

PROCEDURE: SPDX

VERIFIED BY:

1. Left kidney, nephrectomy: Renal cell carcinoma, classic clear cell type (6.8 cm), Fuhrman nuclear grade 4/4. Tumor extends outside the kidney and into perinephric adipose tissue. Focal angiolymphatic invasion present. Margins negative. See TEMPLATE for details.

I, [REDACTED] signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:r

[REDACTED]

ACCESSION:

OPER DATE: [REDACTED] -2661

REQ DOC:

PROCEDURE: GYDXADD'L

VERIFIED BY: T

This pap test was performed by the ThinPrep method.

PROCEDURE: IGYDX

VERIFIED BY: --

Examination for neoplastic cells:

The cervicovaginal Pap smear is a very important screening test that is extremely useful in the detection of cancerous and precancerous conditions of the uterine cervix. However, this test is not perfect and false negative results, in which cancer or a precancerous condition may be missed, represent a known and expected limitation of this test. Quality assurance studies indicate an irreducible false negative fraction of at least 5%. The patient should be reminded to consult her physician immediately if she experiences any suspicious signs or symptoms, regardless of her Pap test result.

[REDACTED]

[page 7 of 22]
Radiology and Nuclear Medicine Results Text

Status	Requisition Number	Source System
Finalized		RAD

Exam	Exam Date	Order Doctor Name	Order Doctor Number
CT OUTSIDE FILM CONSULT CHEST			

+4

STUDY: REVIEW OF OUTSIDE CT CHEST WITH CONTRAST.

CLINICAL INDICATION: Left renal mass with chest wall pleural metastases.

TECHNIQUE: Outside CT of the chest from [REDACTED] dated [REDACTED] was loaded on the [REDACTED] archive for review. The study was performed at 5 mm collimation, reconstructed at 3 mm, following the administration of intravenous contrast.

COMPARISON: None.

FINDINGS:

Lungs: Biapical scarring.

Small bilateral pulmonary nodules are noted as follows on series 8:

Less than 2-3 mm right upper lobe nodules on image #28, 38 and 40.

Less than 2 mm middle lobe nodules image #51 and 55.

5 and 3 mm peripheral subpleural right lower lobes superior segment nodules, image #42 and image #49.

2 mm left apical nodules image #14 and 16 and 5 mm nodule image #20.

2 to 3 mm left upper lobe nodule image #41.

5 mm lingular nodules on image #44 and 47.

2-4 mm nodules in the left lower lobe on image numbers 35, 37, 38, 44, 63 and 68.

Airway: The central tracheobronchial tree is unremarkable.

Lymph nodes: Few nonenlarged mediastinal lymph nodes are noted.

Pleura: There is a small left pleural effusion.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: The central pulmonary arteries are unremarkable.

Heart and pericardium: Unremarkable. No pericardial effusion.

Lower neck/mediastinum: There is a 5.9 x 5.3 x 2.9 cm irregular heterogeneously enhancing left cardiophrenic angle mass with a broad contact with the adjacent anterolateral chest wall between the 6th -8th anterior ribs, and the diaphragm. The pleural effusion abuts the mass at its inferior edge.

[page 8 of 22]
Baseline

Visualized thoracic skeleton and chest wall: There are no destructive osseous lesions.

Visualized upper abdomen: Please refer to the separately dictated abdomen and pelvic CT report.

IMPRESSION:

1. Large heterogenous left anterior cardiophrenic angle mass with broad contact with the adjacent chest wall and diaphragm, and involvement of either of these is possible. The mass is compatible with renal metastases.
2. Multiple bilateral pulmonary parenchymal nodules are concerning for metastases.
3. Left pleural effusion is in contact with the left cardiophrenic angle mass and is concerning for a malignant effusion.

PLEASE NOTE: Our interpretation of studies performed at an outside institution is limited by factors including the absence of technical specifics of the image, undisclosed clinical information and the unavailability of the original interpretation. Specialists at the institution that performed the study may have access to information not available to us that could make a difference in this interpretation. We suggest that you obtain the original interpretation from the site where the study was performed.

Caregiver	Doctor Number	Service Role
		Signed by
		Radiology Staff

[page 9 of 22]
Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Best Response

Ordering Practitioner [REDACTED]

Procedure(s) Performed: CT ABDOMEN PELVIS W IV CONTRAST

Date of Service: [REDACTED] +568

CT abdomen and pelvis with contrast [REDACTED] +568

Clinical history: Metastatic kidney cancer, posttreatment, follow-up.

Technique: Axial CT images of the abdomen and pelvis were obtained with oral and intravenous contrast (125ml of Isovue-300). DFOV 34.0 cm.

Comparison [REDACTED] +431

Findings:

Abdomen:

Dedicated CT images of the chest were also obtained and will be reported separately. Diffuse hepatic steatosis is present. Subcentimeter low attenuation focus in right hepatic lobe on image 476 series 3, too small to definitely characterize, but similar to prior study. The spleen, pancreas, gallbladder, biliary tree, and adrenal glands are unremarkable. There is a 1.0 cm low-attenuation focus in the right interpolar region which is too small to definitely characterize, but has decreased in size from the prior study and may represent a cyst. Status post left nephrectomy. No soft tissue mass in the operative fossa to suggest local tumor recurrence. Bowel is grossly nonobstructive. .

Pelvis:

Urinary bladder is grossly unremarkable. Uterus is anteverted, with heterogeneous appearance, probably due to echo. No enlarged lymph nodes. No substantial free fluid.

Mild atherosclerotic vascular calcifications. No destructive osseous lesions. Few stable sclerotic foci in the axial skeleton likely

[page 10 of 22]
represent bone islands.

1. Postoperative changes from prior left nephrectomy. No soft tissue mass in operative bed to suggest local recurrence. No enlarged lymph nodes.

Best Response

2. Heterogeneous appearance of the uterus, perhaps due to fibroids and/or patient's station in menstrual cycle.

3. Diffuse hepatic steatosis. Low attenuation focus in right kidney is too small to definitely characterize, but smaller than prior study, perhaps regression of a cyst. Attention to this on follow up is suggested.

4. Dedicated chest CT report will be issued separately.
Signed By:

I have personally viewed the examination and agree with the interpretation.

Date/Time

+568

[page 11 of 22]
Results

CT THORAX W IV CONTRAST

Narrative

PROCEDURE: CT CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: met kidney cancer, eval mets post treatment

COMPARISON: [REDACTED] +431

Best Response

TECHNIQUE: Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 1.25 mm slice thickness. MIP and coronal & sagittal MPR images were generated and reviewed. (DFOV = 34 cm)

FINDINGS:

Lower neck/thyroid: Unremarkable.

Lungs: Stable 4 mm groundglass nodule at the right apex image 53 of series 3. Redemonstration of calcified nodule in the middle lobe. Surgical staple lines in the right lower lobe with redemonstration of atelectasis or scarring. Stable 4 mm left upper lobe nodule image 60.

Central airway: Unremarkable.

Pleura: No pleural effusion, thickening or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: No detectable coronary arterial calcification. The heart size is within normal limits. Small pericardial effusion.

Lymph nodes: Interval significant decrease in size in previously noted necrotic lymph nodes. For example subcarinal lymph node on image 170 of series 3 measures 8mm and previously measured 22 mm. Right hilar lymph node measures 5 mm on image 212 and previously measured to 11 mm.

Mediastinum: Unremarkable.

Thoracic spine and chest wall: Unremarkable, with normal thoracic vertebral body heights.

Other Lines/Tubes/Devices/Hardware: None

Visualized upper abdomen: Please refer to separate CT abdomen and pelvis report.

IMPRESSION:

1. Interval significant decrease in size in previously noted necrotic enlarged mediastinal lymph nodes compatible with treatment response.

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
[REDACTED]	[REDACTED]	[REDACTED]	1	[REDACTED]	[REDACTED] MD	[REDACTED]	[REDACTED]
+568				+568			+568

[page 12 of 22]
Results

CT HEAD W IV CONTRAST

Narrative

CT HEAD WITH CONTRAST PERFORMED [REDACTED] +932

CLINICAL INDICATION: Metastatic renal carcinoma.

Progression

COMPARISON: CT head performed [REDACTED] +405

TECHNIQUE: 5 mm axial contrast enhanced CT images of the head were obtained after the uneventful administration of 125 cc Isovue-300 intravenous contrast medium.

FINDINGS:

Interval development of multiple confluent lytic lesions in the right parietal calvarium which is markedly more extensive than on the prior examination. This is concerning for osseous metastatic disease. The lesions erode the inner table of the skull and extends to involve the adjacent dura and superior sagittal sinus. There is no evidence of associated mass effect on the underlying brain.

There is no evidence of abnormal intracranial enhancement. There is no evidence of acute intracranial hemorrhage mass effect or shift of midline structures. The size and configuration of the ventricular system is within normal limits for the patient's stated age. The visualized paranasal sinuses and mastoid air cells are clear.

IMPRESSION:

Interval development of confluent lytic foci involving the right parietal calvarium with erosion of the inner table and suggestion of subtle intracranial extension. No evidence of mass effect on the underlying brain parenchyma. Possible dural extension cannot be excluded. Further assessment with contrast enhanced MRI is more sensitive for the evaluation of intracranial extension and can be obtained as clinically warranted.

These findings were discussed with referring physician [REDACTED] on [REDACTED] +932

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
-----------	-----------	--------------------	--------	-------------	---------------------	--------	-----------

+932

+932

+932

[page 13 of 22]
[REDACTED]

Patient Name:

MRN:

DOB:

Ordering Practitioner:

Progression

Procedure(s) Performed: CT ABDOMEN PELVIS W IV CONTRAST

Date of Service: [REDACTED] +932

CT abdomen and pelvis with contrast [REDACTED] +932

Clinical history: Metastatic kidney cancer, follow-up

Technique: Axial CT images of the abdomen and pelvis were obtained with oral and intravenous contrast (125ml of Isovue-300). DFOV 34.0 cm.

Comparison: [REDACTED] +838

Findings:

Abdomen:

Dedicated CT images of the chest were also obtained and will be reported separately. There is diffuse hepatic steatosis with some sparing near the porta hepatis -- this somewhat limits evaluation for low attenuation lesions. Subcentimeter low-attenuation focus toward the right hepatic dome (image 490 series 3), too small to definitively characterize by CT, but likely similar to prior study given degree of steatosis/technique. No dominant new hepatic lesion seen. The spleen, pancreas, gallbladder, biliary tree, adrenal glands, and right kidney are unremarkable. Postoperative from left nephrectomy. No abnormal soft tissue in operative bed. Bowel is grossly nonobstructive. No enlarged lymph nodes. No substantial free fluid.

Pelvis:

The urinary bladder is grossly unremarkable. Uterus is present, anteverted. Heterogeneous enhancing foci in the fundus and posterior uterine body probably represent fibroids. No enlarged lymph nodes. No substantial free fluid.

Major vascular structures appear patent. No destructive osseous lesions.

[page 14 of 22]
1. Postoperative changes from left nephrectomy. No abnormal soft tissue in the operative fossa. No enlarged lymph nodes.

2. Diffuse hepatic steatosis. Subcentimeter low-attenuation focus in right hepatic dome, too small to definitively characterize by CT, but stable when accounting for technical differences/steatosis. No discrete new hepatic lesion seen.

Progression

3. Dedicated chest CT report will be issued separately.
Signed By: [REDACTED]

I have personally viewed the examination and agree with the interpretation.

Date/Time

[REDACTED] +932

[page 15 of 22]
[REDACTED]

Patient Name: [REDACTED]

MRN:

DOB:

Ordering Practitioner: [REDACTED]

Procedure(s) Performed: CT THORAX W IV CONTRAST

Date of Service: [REDACTED]

+932

Progression

PROCEDURE: CT CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: med kidney cancer, eval mets

COMPARISON: [REDACTED] +838

TECHNIQUE: Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 1.25 mm slice thickness. MIP and coronal & sagittal MPR images were generated and reviewed. (DFOV = 34 cm)

FINDINGS:

Lower neck/thyroid: Unremarkable.

Lungs: Biapical scarring. Surgical staple lines at the right lung base. Stable 3 mm groundglass nodule in the right upper lobe image #85. Stable calcified right upper lobe nodule. Stable 4 mm groundglass nodule in the left upper lobe image 100. No new or growing pulmonary nodules are identified.

Central airway: Unremarkable.

Pleura: No pleural effusion, thickening or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: No detectable coronary arterial calcification. Unremarkable cardiac morphology and pericardium.

[page 16 of 22]
Lymph nodes: No enlarged thoracic lymph nodes.

Mediastinum: Unremarkable.

Thoracic spine and chest wall: Unremarkable, with normal thoracic vertebral body heights.

Other Lines/Tubes/Devices/Hardware: None

Visualized upper abdomen: Please refer to separate CT abdomen and pelvis report.

Progression

1. No significant change when compared to prior study, in particular stable indeterminate pulmonary nodules.

I have personally viewed the examination and agree with the interpretation.

Date/Time

[page 17 of 22]
Patient Name:

MRN:

DOB:

Ordering Practitioner

Procedure(s) Performed: CT ABDOMEN PELVIS W IV CONTRAST

Date of Service: [REDACTED] +342

Prior to [REDACTED] tx

CT abdomen and pelvis with contrast [REDACTED] +342

Clinical history: Metastatic kidney cancer

Technique: Axial CT images of the abdomen and pelvis were obtained with oral and intravenous contrast(125ml of Isovue-300). DFOV 34.0 cm.

Comparison: [REDACTED] +237

Findings:

Abdomen:

Dedicated CT images of the chest were also obtained and will be reported separately. Subcentimeter low-attenuation focus in the anterior segment right hepatic lobe on image 478 series 3, too small to definitively characterize, but stable. No new hepatic lesion identified. The spleen, pancreas, gallbladder, biliary tree, and adrenal glands are unremarkable. Eccentric splenule is noted near the inferior/posterior pole the spleen, stable. Few low-attenuation foci within the right kidney which are grossly stable versus prior study. Postoperative changes from prior left nephrectomy. No suspect soft tissue in the operative fossa to suggest local tumor recurrence. The bowel appears grossly nonobstructive. No enlarged lymph nodes. No substantial free fluid.

Pelvis:

The urinary bladder is grossly unremarkable. Uterus is present, anteverted, with heterogeneous enhancement along the posterior aspect of the uterine body, probably due to fibroids. No enlarged lymph nodes. No substantial free fluid.

[page 18 of 22]
Major vascular structures are patent. Mild atherosclerotic vascular calcifications are noted. No destructive osseous lesions.

+237

Prior to [redacted] tx

1. Overall stable appearance versus [redacted] study. Postoperative changes from prior left nephrectomy. No suspect soft tissue in the operative fossa to suggest local tumor recurrence. No enlarged lymph nodes.

2. Likely fibroid uterus.

Signed By:

I have personally viewed the examination and agree with the interpretation.

Date/Time

+342

[page 19 of 22]
Results

CT THORAX W IV CONTRAST [REDACTED] Order#

Result Report

Open [REDACTED] Result Report

Prior to [REDACTED] tx

Result Information

Status

Final result (Exam

+342

Order Authorizing Provider

Name

Pager#

PACS Images

Show images for CT THORAX W IV CONTRAST

Impression

Narrative

PROCEDURE: CT CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: Metastatic renal cancer.

COMPARISON: [REDACTED] +237

TECHNIQUE: CT chest with contrast - chest protocol. Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 2.5 mm and 1.25 mm slice thickness. (DFOV = 34 cm)

FINDINGS:

Lungs: Status post resection of previously noted right lower lobe nodule. Redemonstration of ill defined spiculated tiny nodules for example right upper lobe image 64 and 81, middle lobe image 243 and left upper lobe image 83 of series 3.

No new pulmonary nodules identified.

Airway: Unremarkable.

Pleura: No pleural effusion, thickening or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: Unremarkable.

Lymph nodes: Interval significant increase in size in subcarinal and right hilar lymph nodes. For example:

- subcarinal lymph node on image 193 of series 3 measures 21 x 26 mm and previously measured 7 mm,

[page 20 of 22]
- right hilar lymph node on image 231 measures 12 x 17 mm and previously measured 5 mm,
- right hilar lymph node on image 260 of series 3 measures 9 mm and previously measured 4 mm.

Prior to [redacted] tx

New 10 mm preesophageal lymph node image 217 of series 3.

Lower neck/mediastinum: Low-attenuation lesion in the right thyroid lobe.

Thoracic spine and chest wall: Unremarkable, with normal thoracic vertebral body heights.

Visualized upper abdomen: Please refer to separate reports regarding the findings in the abdomen/pelvis.

IMPRESSION:

1. Status post right lower lobe wedge resection with postsurgical changes. No new pulmonary nodules.
2. Interval significant increase in size in mediastinal lymph nodes as detailed above concerning for metastatic disease progression.

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
+342							

Result History

+342

+342

CT THORAX W IV CONTRAST

on [redacted] Click to view result history

Charges to Be Sent

+301

No log ID found

Charges Sent

No log ID found

Order Information

CT THORAX W IV CONTRAST
on [redacted] +301

Reprint IP Order Requisition

CT THORAX W IV CONTRAST
on [redacted] Reprint IP Requisition
+301

Reprint [redacted] Order Requisition

CT THORAX W IV CONTRAST

[redacted] Reprint [redacted] Requisition
+301

[page 21 of 22]
Results

CT THORAX W IV CONTRAS

Impression

IMPRESSION:

1. There are few new small right lower lobe peribronchial nodules likely inflammatory-infectious. Attention at subsequent follow-up is recommended. Otherwise no definite evidence for metastatic disease.

Narrative

PROCEDURE: CT CHEST WITH CONTRAST - CHEST PROTOCOL

CLINICAL INDICATION: metastatic kidney cancer

COMPARISON: +1814

TECHNIQUE: Helical CT was performed of the chest (lung apices to bases) using 125 mL Isovue-300 nonionic intravenous contrast, without complication. Images were reconstructed at 1.25 mm slice thickness every 0.625 mm. MIP and coronal & sagittal MPR images were generated and reviewed. (DFOV = 34 cm)

FINDINGS:

Lower neck/thyroid: Unremarkable.

Lungs: Suture material noted in the right lower lobe above the right hemidiaphragm. There are a few new tiny 2 to 4 mm peribronchial nodules in the right lower lobe images 336-356 the largest measuring 4 mm in image 356. The distal peribronchial distribution suggests infectious-inflammatory etiologies. No other discrete lung nodules. Small region of scarring in the medial right apex.

Central airway: Unremarkable.

Pleura: No pleural effusion, thickening or pneumothorax.

Thoracic aorta and great vessels: Normal in diameter.

Pulmonary arteries: Unremarkable.

Heart and pericardium: No detectable coronary arterial calcification. Unremarkable cardiac morphology and pericardium.

Lymph nodes: No enlarged thoracic lymph nodes.

Mediastinum: Unremarkable.

Thoracic spine and chest wall: No aggressive bone lesions.

Other Lines/Tubes/Devices/Hardware: None

Visualized upper abdomen: Please see separate report

Latest scan

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
		Phys, Unable To Identify			+1996		
					+1998		
							+1998

+1996

[page 22 of 22]
Results

MRI HEAD AND NECK WO AND W CONTRAST

Impression

IMPRESSION:

1. Overall stable examination of the head and suprahyoid neck as described above.
2. New subtotal opacification of the left mastoid air cells.

Narrative

EXAMINATION: MRI PAROTID. [REDACTED] +1996

HISTORY: 54-year-old female with metastatic kidney cancer, remission for 3 years, follow-up examination of the parotid glands.

COMPARISON: Most recent examination from [REDACTED] was used for comparison.
+1814

TECHNIQUE: Utilizing the 1.5 Tesla Phillips, MRI, multiplanar, multi sequential magnetic resonance imaging of the brain was obtained both before and after the uneventful administration of 20 cc MultiHance IV contrast. Images were obtained following the [REDACTED] cranial nerve VII/parotid protocol.

FINDINGS:

There is again redemonstration of T1 hypointense/T2 hyperintense intraparotid nodule seen within the superficial lobe of the right parotid gland with homogenous enhancement. When compared to the examination dated [REDACTED] there has been no significant change in the size or morphology of the nodule. Additional, slightly smaller nodule within the superficial lobe of the left parotid gland also demonstrates mild enhancement and has not significantly changed. Nonenlarged lymph nodes are seen scattered in the visualized suprahyoid neck. The appearance of the lymph nodes is likely unchanged given the differences in the slice angulation.

The submandibular glands appear symmetric. No new changes are noted. The globes, extraocular musculature and retro-ocular soft tissues are normal. There is redemonstration of fluid signal seen within the left C1/C2 articulation, which is not significantly changed. Fluid signal is noted in the left mastoid air cells, which is a new finding compared to [REDACTED]

+1814

The brain volume and sulcal pattern are appropriate for the patient's chronological age. The ventricles are normal in size without evidence of hydrocephalus. There are few punctate foci of FLAIR hyperintensity in the deep cerebral white matter. There is no focal area of restricted diffusion. There is no pathologic parenchymal or leptomeningeal enhancement. There are stable postoperative changes related to craniotomy in the right parietal region.

Result Information

Exam Date	Exam Time	Prelim Radiologist	Pager#	Prelim Date	Reading Radiologist	Pager#	Read Date
[REDACTED]	[REDACTED]	Phys, Unable To Identify	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	+1996
+1996		[REDACTED]					
				+1996			

Source: NCI Genomic Data Commons file 44aa8f8e-035d-4281-934f-94bfe72a770d (ER0024 ER-AE8R Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).